Somatic mutation profile of tumor specimen MP2PRT-PAVGTD-TBP1-A (aliquot MP2PRT-PAVGTD-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGTD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,141 days).
Specimen MP2PRT-PAVGTD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0160a122-434a-46b4-85e7-b3b9fa85e44d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGTD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGTD-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49580ec-fdf9-4dc8-b0e3-87c8ea6553dc

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIMS1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757314703, COSV53469571; called by muse, mutect2, varscan2
- SOX3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 181/376 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65167845; called by muse, mutect2, varscan2
- A2ML1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 83/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV3-1 | c.341del p.A114Dfs*? | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by pindel*, varscan2
- UBA2 | c.691_692insGTCCG p.E231Gfs*39 | Frame Shift Ins (INS) | VAF 30/196 reads (15%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.173); called by muse, mutect2
- NLRP5 | c.3258C>T p.C1086= | Silent (SNP) | VAF 45/367 reads (12%) | catalogued as rs764666206, COSV66763493; called by muse, mutect2, varscan2
